Somatic mutation profile of tumor specimen 0DM6A0 from CCDI case PBCACJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (653 days).
Specimen 0DM6A0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5265f206-2d0a-4e54-a23b-8fbd05389d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM69J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/863456a7-c312-4553-b3ed-46d983523837

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPB41L4B | c.633G>A p.A211= | Splice Region (SNP) | VAF 174/448 reads (39%) | catalogued as rs370668187; called by muse, mutect2, varscan2
- SMARCB1 | c.721G>T p.E241* (on ENST00000263121; = p.E287* on NM_003073.5) | Nonsense Mutation (SNP) | VAF 138/194 reads (71%) | catalogued as CM108556; called by muse, mutect2, varscan2
- ORC1 | c.549A>T p.A183= | Silent (SNP) | VAF 22/832 reads (3%) | catalogued as COSV65365071; called by muse, mutect2
